Somatic mutation profile of tumor specimen TCGA-HQ-A2OF-01A (aliquot TCGA-HQ-A2OF-01A-11D-A26M-08) from TCGA case TCGA-HQ-A2OF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 52.1 years (19,016 days).
Specimen TCGA-HQ-A2OF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bb7e6e9-c4fd-4227-b2e3-f513649c278b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HQ-A2OF-10B (Blood Derived Normal), aliquot TCGA-HQ-A2OF-10B-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a28784d-93a9-47c6-a4cf-8e90274fb88e

The open-access MAF lists 120 somatic variants for this specimen: 79 protein-altering or splice-affecting, 36 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 36, Nonsense Mutation 5, Frame Shift Del 4, RNA 3, 3'UTR 1, Intron 1, Splice Site 1, Splice Region 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 289/340 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 26/33 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANO8 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50191960; called by muse, varscan2
- AQP10 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as rs778846975, COSV61474642; called by muse, mutect2, varscan2
- ARNT2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs758605791, COSV57588605; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752513014, COSV57281371; called by muse, mutect2, varscan2
- BRDT | c.1565T>G p.I522R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62866407; called by muse, mutect2, varscan2
- CAMSAP1 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs770936305, COSV56722710; called by muse, mutect2, varscan2
- CDC25C | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs1187007571, COSV60400626; called by muse, mutect2, varscan2
- CHRM4 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0.153); catalogued as rs750280509, COSV59185864; called by muse, mutect2, varscan2
- CSMD3 | c.8614+1G>A p.X2872_splice (on ENST00000297405 / NM_001363185.1; = p.X2703_splice on NM_052900.3) | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99826963; called by muse, mutect2
- CYP7B1 | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.617); catalogued as rs1173341823, COSV100043002; called by muse, mutect2
- DGKI | c.1873G>T p.D625Y | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV55952073, COSV55966318; called by muse, mutect2, varscan2
- DLL1 | c.1867G>A p.G623R | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs763858182, COSV64538136; called by muse, mutect2, varscan2
- DNAJC5 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs796052411, COSV62672765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPP8 | c.1199C>T p.T400I (on ENST00000341861 / NM_001320875.2; = p.T384I on NM_017743.6) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV55681440; called by muse, mutect2, varscan2
- DROSHA | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60772312; called by muse, mutect2, varscan2
- EGR1 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53520547; called by muse, mutect2, varscan2
- EML5 | c.3169G>A p.V1057I | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs779543531, COSV61349785; called by muse, mutect2, varscan2
- EPHA6 | c.1862G>A p.S621N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV67585776, COSV67594444; called by muse, mutect2, varscan2
- EVPL | c.5621G>A p.R1874H | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs769872374, COSV56913999; called by muse, mutect2, varscan2
- FBP2 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547312807, COSV64695230; called by muse, mutect2, varscan2
- FCN2 | c.429C>T p.T143= | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as rs532739715, COSV99391392; called by muse, varscan2
- FRMD6 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.067); catalogued as rs1256364872, COSV61087790; called by muse, mutect2, varscan2
- GABRB3 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs777882335, COSV54663217; called by muse, mutect2, varscan2
- GNPDA1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs758634512, COSV60942898, COSV60943313; called by muse, mutect2, varscan2
- GPATCH8 | c.1202A>C p.H401P | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59196651; called by muse, mutect2, varscan2
- GREB1 | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); catalogued as rs371609460; called by muse, mutect2, varscan2
- GTF3C3 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55833640; called by muse, mutect2, varscan2
- HAUS7 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 47/89 reads (53%) | catalogued as COSV100444328; called by muse, mutect2, varscan2
- HOXB6 | c.37A>C p.T13P | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV99494749; called by muse, mutect2
- HUWE1 | c.11911C>T p.R3971W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53357667; called by muse, mutect2, varscan2
- JMJD1C | c.950C>G p.S317* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as COSV101232485; called by muse, mutect2, varscan2
- KCNN3 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs764366056, COSV55222742; called by muse, varscan2
- KPRP | c.1620G>C p.E540D | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV64221379, COSV64222480; called by muse, mutect2, varscan2
- KRTAP27-1 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1443161321, COSV101239746, COSV67001490; called by muse, mutect2, varscan2
- LDOC1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as COSV65159540; called by muse, mutect2, varscan2
- LIMK2 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs1238726323, COSV100059004, COSV59183633; called by muse, mutect2, varscan2
- LMAN1L | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV59000595; called by muse, mutect2, varscan2
- LRP1B | c.13795G>A p.A4599T | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV67254148; called by mutect2, varscan2
- MAOA | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs368201051, COSV100109084, COSV58644536; called by muse, mutect2, varscan2
- METTL17 | c.902C>G p.A301G | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV53870657; called by muse, mutect2, varscan2
- MMP16 | c.1149del p.F384Sfs*44 | Frame Shift Del (DEL) | VAF 68/154 reads (44%) | catalogued as COSV54179820; called by mutect2, pindel, varscan2
- MMP2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.28); catalogued as rs773564814, COSV54600773; called by muse, mutect2, varscan2
- MRGPRX1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as rs567589026, COSV57107622; called by muse, mutect2, varscan2
- MSH2 | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.876); catalogued as CS068752, COSV99254574; called by muse, varscan2
- NFATC2 | c.2774C>T p.T925M | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs201617985, COSV65359158; called by muse, varscan2
- OR10Z1 | c.239G>T p.R80I | Missense Mutation (SNP) | VAF 145/223 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV63525867; called by muse, mutect2, varscan2
- PCDHA7 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.846); catalogued as COSV65342015; called by muse, varscan2
- PCNX3 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV63139178; called by muse, mutect2
- PLEC | c.4537G>T p.A1513S (on ENST00000322810 / NM_201380.4; = p.A1403S on NM_000445.5) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV100519199; called by muse, mutect2
- PRICKLE1 | c.560T>A p.L187H | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61545177; called by muse, mutect2, varscan2
- PRKDC | c.1349G>T p.S450I | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as rs951494739, COSV58059463; called by muse, mutect2
- RAB40C | c.811dup p.Q271Pfs*7 | Frame Shift Ins (INS) | VAF 23/60 reads (38%) | catalogued as rs1555457247; called by mutect2, varscan2
- RAP1GDS1 | c.1076T>G p.V359G (on ENST00000408927 / NM_001100427.2; = p.V360G on NM_021159.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV52790016; called by muse, mutect2, varscan2
- RDH16 | c.938C>G p.P313R | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62458510; called by muse, mutect2, varscan2
- SLC26A9 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778478558, COSV61604513; called by muse, mutect2, varscan2
- SRCAP | c.1319G>C p.G440A | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.415); catalogued as COSV52677841; called by muse, mutect2, varscan2
- SYNE1 | c.9855C>G p.F3285L (on ENST00000367255 / NM_182961.4; = p.F3292L on NM_033071.3) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV55053269; called by muse, mutect2, varscan2
- TAF1L | c.2519G>A p.R840Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.274); catalogued as rs546961616, COSV54266028, COSV99645243; called by mutect2, varscan2
- TBC1D10C | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as rs1055338188, COSV56704356; called by muse, mutect2, varscan2
- TBXT | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as COSV51618943; called by muse, mutect2, varscan2
- TMC5 | c.1899C>A p.C633* (on ENST00000396229 / NM_001105248.1; = p.C387* on NM_024780.5) | Nonsense Mutation (SNP) | VAF 28/139 reads (20%) | catalogued as COSV99572877; called by muse, mutect2, varscan2
- TMTC2 | c.1183G>T p.V395F | Missense Mutation (SNP) | VAF 84/93 reads (90%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV58278219; called by muse, mutect2, varscan2
- TOP3A | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368210504; called by muse, mutect2, varscan2
- TRHDE | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371645003; called by muse, mutect2, varscan2
- TRPM8 | c.2138G>A p.R713K | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV61223228; called by muse, mutect2, varscan2
- TTN | c.19567G>T p.G6523* (on ENST00000591111; = p.G5596* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100630626; called by muse, mutect2, varscan2
- TTN | c.4714C>T p.R1572* (on ENST00000591111; = p.R1526* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as rs1554008881, COSV60315148; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VCAN | c.9580G>A p.E3194K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54112371; called by muse, mutect2, varscan2
- WIPF1 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.436); catalogued as rs1289462181, COSV55818352; called by muse, mutect2, varscan2
- ZNF131 | c.1841A>G p.E614G (on ENST00000509156 / NM_001330707.2; = p.E580G on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.932); catalogued as COSV61003825; called by muse, mutect2, varscan2
- ZNF691 | c.547C>T p.R183C (on ENST00000372502; = p.R152C on NM_015911.3) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.284); catalogued as rs778602648, COSV65289527; called by muse, mutect2, varscan2
- ABCC3 | c.1663del p.V555Cfs*24 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by pindel, varscan2
- CDH1 | c.1199_1201del p.D400del | In Frame Del (DEL) | VAF 32/131 reads (24%) | called by mutect2, pindel, varscan2
- EXT1 | c.642_670del p.M215Kfs*7 | Frame Shift Del (DEL) | VAF 48/196 reads (24%) | called by mutect2, pindel
- PLEKHG6 | c.419_429del p.T140Ifs*42 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | called by mutect2, pindel, varscan2
- POLR2A | c.3667G>A p.D1223N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PRAMEF20 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 100/259 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ABCA13 | c.5592G>A p.L1864= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV70038967; called by muse, mutect2, varscan2
- ADAMTS9 | c.2373C>T p.D791= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs769078401, COSV55782484; called by muse, mutect2, varscan2
- APBA2 | c.24C>T p.S8= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs770399185, COSV68790732; called by muse, varscan2
- ARID3C | c.732C>T p.G244= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs904360277, COSV52408369; called by muse, mutect2, varscan2
- BMP5 | c.210T>A p.P70= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV63705171; called by muse, mutect2, varscan2
- CBLL1 | c.1377G>A p.G459= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as COSV56029899; called by muse, mutect2, varscan2
- CTPS1 | c.1053C>T p.P351= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs746923692, COSV65453466, COSV65454036; called by muse, mutect2, varscan2
- FCGR2C | c.909C>T p.D303= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs760297358, COSV100913163; called by muse, mutect2, varscan2
- H2BC13 | c.345C>G p.G115= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV62441036; called by muse, mutect2, varscan2
- H3C8 | c.408G>T p.A136= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as COSV59953107, COSV59953470; called by muse, varscan2
- HTR1A | c.459C>T p.A153= | Silent (SNP) | VAF 41/46 reads (89%) | catalogued as COSV60502176; called by muse, mutect2, varscan2
- JPH1 | c.1011C>A p.V337= | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as COSV60613337; called by muse, mutect2, varscan2
- JPH4 | c.882C>T p.F294= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV62508554; called by muse, mutect2, varscan2
- KCNN3 | c.1698G>A p.A566= (on ENST00000618040 / NM_001204087.1; = p.A551= on NM_002249.6) | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs777061224, COSV55217337; called by muse, mutect2, varscan2
- LAMA5 | c.4803C>T p.N1601= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs146887751; called by muse, mutect2, varscan2
- MAGI2 | c.168C>T p.S56= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV62684237; called by muse, mutect2, varscan2
- MITF | c.1440C>T p.D480= (on ENST00000448226 / NM_006722.3; = p.D380= on NM_000248.4) | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs756305763, COSV58830674; called by muse, mutect2, varscan2
- MYBPC2 | c.2289C>T p.I763= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs775231133, COSV63093660; called by muse, mutect2, varscan2
- NES | c.3675C>T p.Y1225= | Silent (SNP) | VAF 32/158 reads (20%) | catalogued as rs749231946, COSV63962123; called by muse, mutect2, varscan2
- NID1 | c.3048T>C p.I1016= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV51625518; called by muse, mutect2, varscan2
- NLRP14 | c.1281G>T p.L427= | Silent (SNP) | VAF 39/70 reads (56%) | catalogued as COSV55070230; called by muse, mutect2, varscan2
- OR1K1 | c.18G>A p.E6= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV52957015; called by muse, mutect2, varscan2
- PGR | c.1023G>A p.P341= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs762789408, COSV54807342; called by muse, mutect2, varscan2
- PLCXD1 | c.414G>A p.S138= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs369964265, COSV67542351; called by muse, mutect2
- PMAIP1 | c.133C>T p.L45= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV54054269; called by muse, mutect2, varscan2
- PSAPL1 | c.1341C>T p.P447= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1215089943, COSV59842225; called by muse, mutect2, varscan2
- RAB6B | c.114C>T p.F38= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as rs1351903220, COSV53314956; called by muse, mutect2, varscan2
- RSBN1L | c.57C>T p.T19= | Silent (SNP) | VAF 28/182 reads (15%) | catalogued as rs376697374; called by muse, mutect2
- SELP | c.2052C>A p.L684= | Silent (SNP) | VAF 112/523 reads (21%) | catalogued as COSV55255763; called by muse, mutect2, varscan2
- SLCO3A1 | c.1530G>A p.A510= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs375014073; called by muse, mutect2, varscan2
- SRGAP3 | c.2961G>A p.A987= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs199848187, COSV64537031; called by muse, mutect2, varscan2
- TANK | c.1272G>A p.E424= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs767052443, COSV52046790; called by muse, mutect2, varscan2
- TLE2 | c.709C>T p.L237= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV53581478; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2733G>A p.K911= | Silent (SNP) | VAF 57/109 reads (52%) | catalogued as COSV64101962; called by muse, mutect2, varscan2
- TTN | c.46854G>A p.V15618= (on ENST00000591111; = p.V8194= on NM_003319.4) | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV60228638; called by muse, mutect2, varscan2
- WFDC13 | c.216A>G p.S72= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as COSV57914496; called by muse, mutect2, varscan2
- CD46 | c.*71C>T | 3'UTR (SNP) | VAF 7/48 reads (15%) | catalogued as rs1451492925, COSV59732584, COSV59734733; called by muse, mutect2, varscan2
- DENND10P1 | n.1150C>T | RNA (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- FOLH1B | n.851C>T | RNA (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- NBPF7 | n.578A>G | RNA (SNP) | VAF 8/19 reads (42%) | catalogued as rs750173584; called by muse, mutect2, varscan2
- NUDCD3 | c.509+16936G>A | Intron (SNP) | VAF 48/230 reads (21%) | catalogued as rs61734962, COSV62651824; called by muse, mutect2, varscan2
